Somatic mutation profile of tumor specimen TCGA-DX-A6B9-01A (aliquot TCGA-DX-A6B9-01A-12D-A32I-09) from TCGA case TCGA-DX-A6B9, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Overlapping lesion of connective, subcutaneous and other soft tissues; Age at diagnosis: 45.3 years (16,561 days).
Specimen TCGA-DX-A6B9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4e4f2ca-b567-4c21-a9f3-866037bf49fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A6B9-10A (Blood Derived Normal), aliquot TCGA-DX-A6B9-10A-01D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7afef782-d85e-482b-b6f0-12187faaf273

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A1 | c.2242C>T p.P748S | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101010912; called by muse, varscan2
- GATA4 | c.1295T>C p.L432S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM119354, COSV100632751; called by muse, mutect2, varscan2
- MAN1B1 | c.1897G>T p.V633F | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777270726, COSV65371728; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDH12 | c.2701C>T p.Q901* | Nonsense Mutation (SNP) | VAF 32/81 reads (40%) | catalogued as rs142096693, COSV99185725; called by muse, mutect2, varscan2
- PCDHB3 | c.1954C>T p.R652C | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); catalogued as rs1395640142, COSV99164091; called by muse, mutect2, varscan2
- PSMA8 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); catalogued as rs371854509, COSV57605327; called by muse, mutect2, varscan2
- SCAF11 | c.2219A>G p.D740G | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.321); catalogued as COSV101014015; called by muse, mutect2, varscan2
- COL4A1 | c.2316C>T p.I772= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as rs377593990; called by muse, varscan2
- FYB1 | c.1281G>A p.P427= | Silent (SNP) | VAF 32/84 reads (38%) | catalogued as rs115158663; called by muse, mutect2, varscan2
- MAGEA1 | c.765G>A p.P255= | Silent (SNP) | VAF 47/122 reads (39%) | catalogued as rs782573461, COSV100756601; called by muse, mutect2, varscan2
